Somatic mutation profile of tumor specimen MMRF_1185_1_BM_CD138pos (aliquot MMRF_1185_1_BM_CD138pos_T1_KAS5U_L01221) from MMRF case MMRF_1185, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.0 years (24,830 days).
Specimen MMRF_1185_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cdbfa33-58de-4b69-a1f3-58125acd3c36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1185_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1185_1_PB_Whole_C2_KAS5U_L01233; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6079d1f-af34-4bfc-8d31-062c46d7ed62

The open-access MAF lists 129 somatic variants for this specimen: 43 protein-altering or splice-affecting, 18 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 38, Missense Mutation 37, Silent 18, Intron 11, 5'Flank 10, 5'UTR 6, 3'Flank 3, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAX | c.106A>T p.R36W | Missense Mutation (SNP) | VAF 14/52 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52418001; called by muse, mutect2, varscan2
- CD74 | c.74C>G p.S25C | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1356857314; called by muse, mutect2, varscan2
- CFHR5 | c.127T>C p.S43P | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1272745276; called by muse, mutect2, varscan2
- ELP3 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as rs761573732, COSV99833702; called by muse, mutect2, varscan2
- H2BC10 | c.129C>G p.Y43* | Nonsense Mutation (SNP) | VAF 31/149 reads (21%) | catalogued as rs575291570; called by muse, mutect2, varscan2
- HDX | c.854A>G p.K285R | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.272); catalogued as rs373071110; called by muse, mutect2, varscan2
- IGKV4-1 | c.328G>C p.A110P | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs775181261; called by muse, mutect2, varscan2
- IMPG1 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs200194885, COSV100886419, COSV64054434; called by muse, mutect2, varscan2
- KIAA0513 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs766399754, COSV50740513; called by muse, mutect2, varscan2
- PCDHB6 | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 29/140 reads (21%) | catalogued as rs1554277424, COSV50689884; called by muse, mutect2, varscan2
- PXDN | c.3826G>A p.D1276N | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs750342758, COSV99413106; called by muse, mutect2, varscan2
- RFPL3 | c.730C>T p.R244* (on ENST00000249007 / NM_001098535.1; = p.R215* on NM_006604.2) | Nonsense Mutation (SNP) | VAF 50/218 reads (23%) | catalogued as rs1193331784; called by muse, mutect2, varscan2
- SYT13 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1210110449; called by muse, mutect2, varscan2
- ZFPM1 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs551152203, COSV60326503; called by muse, mutect2, varscan2
- AFF3 | c.3311C>T p.P1104L | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- AHNAK | c.9748G>A p.G3250R | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AMPD3 | c.1431-8T>A | Splice Region (SNP) | VAF 22/91 reads (24%) | called by muse, varscan2
- BRPF1 | c.395A>G p.N132S | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CAPS | c.108C>A p.D36E | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CD19 | c.470_473del p.Y157Cfs*23 | Frame Shift Del (DEL) | VAF 21/96 reads (22%) | called by mutect2, pindel, varscan2
- DDX50 | c.2109A>C p.R703S | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAJC13 | c.4095T>A p.D1365E | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FUBP3 | c.1120G>A p.G374S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLRA4 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IGHD2-21 | c.2G>C p.S1T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2
- IGKV5-2 | c.298T>A p.S100T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.042); called by muse, varscan2
- KLF9 | c.53T>G p.I18S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- LIG3 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MASP1 | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MMP21 | c.953A>G p.D318G | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPAT | c.1078_1087del p.L360Kfs*4 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- NUDT7 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- PCLO | c.2356C>A p.Q786K | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSIP1 | c.1471C>G p.Q491E | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.9); called by muse, mutect2
- SIGLEC12 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC12A7 | c.1268T>C p.L423P | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SLC25A13 | c.2006A>C p.K669T | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPGS1 | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- TSC22D4 | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- UBE2G1 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UTP20 | c.4526T>C p.V1509A | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB24 | c.1652A>G p.E551G | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF496 | c.1424A>G p.N475S | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- C8B | c.1377C>T p.N459= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs1301353438; called by muse, mutect2
- CNTFR | c.1041G>A p.S347= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs560955916; called by muse, mutect2, varscan2
- DSC1 | c.1461C>A p.G487= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs1252910723; called by muse, mutect2, varscan2
- GREB1 | c.1242C>T p.S414= | Silent (SNP) | VAF 39/230 reads (17%) | called by muse, mutect2, varscan2
- HS3ST1 | c.28C>T p.L10= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs1354362838; called by muse, mutect2, varscan2
- IGKV1-5 | c.270G>A p.G90= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as rs534891049; called by muse, mutect2, varscan2
- IP6K2 | c.381C>A p.T127= | Silent (SNP) | VAF 42/210 reads (20%) | called by muse, mutect2, varscan2
- MAGEB6 | c.645C>A p.S215= | Silent (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- MCM3AP | c.4305C>T p.A1435= | Silent (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- PRR16 | c.382A>C p.R128= (on ENST00000407149 / NM_001300783.2; = p.R105= on NM_016644.2) | Silent (SNP) | VAF 30/135 reads (22%) | called by muse, mutect2, varscan2
- SETD1B | c.3084G>A p.E1028= | Silent (SNP) | VAF 28/125 reads (22%) | called by muse, mutect2, varscan2
- SLC15A2 | c.1203A>C p.I401= | Silent (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- SLC22A3 | c.1407A>G p.G469= | Silent (SNP) | VAF 21/125 reads (17%) | called by muse, mutect2, varscan2
- SLC35D3 | c.858C>T p.G286= | Silent (SNP) | VAF 24/125 reads (19%) | called by muse, mutect2, varscan2
- ST18 | c.51C>T p.T17= | Silent (SNP) | VAF 66/235 reads (28%) | catalogued as rs147519154; called by muse, mutect2, varscan2
- VPS13D | c.1887C>T p.S629= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- ZDHHC19 | c.258C>A p.I86= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV56348416, COSV56348978; called by muse, mutect2, varscan2
- ZMIZ1 | c.3021C>T p.T1007= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as rs1467059857; called by muse, mutect2, varscan2
- ACO2 | c.-17C>T | 5'UTR (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- AEN | c.*341C>G | 3'UTR (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- AGTR2 | c.*1496T>G | 3'UTR (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- AR | c.*2398A>G | 3'UTR (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- ATM | c.4909+130T>A | Intron (SNP) | VAF 49/268 reads (18%) | called by muse, mutect2, varscan2
- ATP6V1G1 | c.*654_*657delinsTCC | 3'UTR (DEL) | VAF 6/70 reads (9%) | called by pindel, varscan2*
- ATRX | c.*1449A>G | 3'UTR (SNP) | VAF 6/26 reads (23%) | catalogued as rs1454365033; called by muse, mutect2
- BCL7A | chr12:122021012 G>T | 5'Flank (SNP) | VAF 24/135 reads (18%) | called by muse, varscan2
- BCL7A | chr12:122021038 G>A | 5'Flank (SNP) | VAF 24/130 reads (18%) | called by muse, varscan2
- BRWD3 | c.*1379A>C | 3'UTR (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- CCER1 | c.-149G>T | 5'UTR (SNP) | VAF 16/92 reads (17%) | catalogued as rs1028807201; called by muse, mutect2, varscan2
- CCSER1 | c.*135_*160delinsTCTTAGTCATAAACAAAGACTTGTGGGT | 3'UTR (INS) | VAF 12/91 reads (13%) | called by pindel, varscan2*
- CHI3L1 | c.1011+25C>T | Intron (SNP) | VAF 38/139 reads (27%) | catalogued as rs779084360; called by muse, mutect2, varscan2
- COL2A1 | c.293-10del | Intron (DEL) | VAF 9/84 reads (11%) | called by mutect2, pindel, varscan2
- COL5A1 | c.*403G>A | 3'UTR (SNP) | VAF 65/161 reads (40%) | called by muse, mutect2, varscan2
- COX11 | c.*1630T>C | 3'UTR (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- CTDSPL2 | c.*1826A>T | 3'UTR (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- DBNDD1 | c.*1110G>T | 3'UTR (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- DENND4A | chr15:65661750 G>A | 3'Flank (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- EIF4A2 | c.*176C>A | 3'UTR (SNP) | VAF 31/125 reads (25%) | called by muse, mutect2, varscan2
- ENPP1 | c.*3578G>A | 3'UTR (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- EPB41L4A | c.1739+87T>A | Intron (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- GRHL2 | c.*903C>A | 3'UTR (SNP) | VAF 24/143 reads (17%) | called by muse, mutect2, varscan2
- GTF2A1L | chr2:48617837 C>T | 5'Flank (SNP) | VAF 19/126 reads (15%) | catalogued as rs1350364000; called by muse, mutect2, varscan2
- H4C6 | c.-33G>A | 5'UTR (SNP) | VAF 51/193 reads (26%) | catalogued as rs776893140; called by muse, mutect2, varscan2
- HLA-DOA | c.*2078G>A | 3'UTR (SNP) | VAF 30/114 reads (26%) | called by muse, mutect2, varscan2
- IQSEC1 | c.*1997A>T | 3'UTR (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- LARP1B | c.*7C>G | 3'UTR (SNP) | VAF 31/183 reads (17%) | called by muse, mutect2, varscan2
- LGALS9 | chr17:27630424 C>G | 5'Flank (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- LTB | c.162+128G>A | Intron (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- MAN2A1 | c.3172-68G>C | Intron (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2
- MID2 | c.-479T>C | 5'UTR (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- MIR5195 | chr14:106851229 A>C | 5'Flank (SNP) | VAF 42/150 reads (28%) | catalogued as rs578215375; called by muse, varscan2
- MIR5195 | chr14:106851353 C>T | 5'Flank (SNP) | VAF 26/90 reads (29%) | catalogued as rs1567940405; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851354 A>T | 5'Flank (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- MIR663A | chr20:26208408 C>A | 5'Flank (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- MRO | c.*751G>A | 3'UTR (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- MTMR12 | c.*1168_*1169dup | 3'UTR (INS) | VAF 4/25 reads (16%) | catalogued as rs1162611083; called by mutect2, varscan2
- NDRG1 | c.-18-513G>A | Intron (SNP) | VAF 20/85 reads (24%) | catalogued as rs144905155, COSV100106507; called by muse, mutect2, varscan2
- NDUFV3 | c.170-5447G>A | Intron (SNP) | VAF 19/95 reads (20%) | catalogued as COSV61088053; called by muse, mutect2, varscan2
- NEUROG1 | c.*605T>A | 3'UTR (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- NOL4 | c.*718C>G | 3'UTR (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- PAPPA2 | c.*2587C>A | 3'UTR (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- PCDH10 | c.*1288A>G | 3'UTR (SNP) | VAF 15/66 reads (23%) | catalogued as rs1346914066; called by muse, mutect2, varscan2
- PCYT1A | c.*3190C>G | 3'UTR (SNP) | VAF 37/164 reads (23%) | called by muse, mutect2, varscan2
- PIM1 | c.*656G>A | 3'UTR (SNP) | VAF 18/79 reads (23%) | catalogued as rs373475716; called by muse, mutect2, varscan2
- PLA2G4A | c.*35T>G | 3'UTR (SNP) | VAF 62/204 reads (30%) | called by muse, mutect2, varscan2
- PLOD2 | c.1128-694T>C | Intron (SNP) | VAF 2/10 reads (20%) | called by muse, mutect2
- PM20D2 | c.*2201A>C | 3'UTR (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2, varscan2
- POLR2F | c.453-15368C>T | Intron (SNP) | VAF 55/239 reads (23%) | called by muse, mutect2, varscan2
- PPP3R1 | c.-286_-283del | 5'UTR (DEL) | VAF 13/71 reads (18%) | called by mutect2, pindel, varscan2
- PRKCSH | chr19:11435666 A>T | 5'Flank (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2
- REX1BD | c.*77T>A | 3'UTR (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- RNF152 | c.*645C>T | 3'UTR (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- RPL32 | chr3:12835900 C>T | 3'Flank (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- RUFY3 | c.-119G>A | 5'UTR (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- SHOX | c.*654C>T | 3'UTR (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- SLC24A3 | c.*759G>A | 3'UTR (SNP) | VAF 41/110 reads (37%) | called by muse, mutect2, varscan2
- SRF | c.*794C>A | 3'UTR (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2
- TAF1 | c.*1659G>A | 3'UTR (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- TECRL | chr4:64276611 T>G | 3'Flank (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- TMEM18 | c.*2000T>A | 3'UTR (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- TMEM47 | c.*2712T>C | 3'UTR (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- TNRC6A | c.*454A>G | 3'UTR (SNP) | VAF 5/76 reads (7%) | catalogued as rs911319646, COSV100169358; called by muse, mutect2
- TRPC5 | c.*1233T>C | 3'UTR (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- TYK2 | c.2466+297C>T | Intron (SNP) | VAF 63/258 reads (24%) | called by muse, mutect2, varscan2
- WDR62 | chr19:36054601 G>A | 5'Flank (SNP) | VAF 24/115 reads (21%) | called by muse, mutect2, varscan2
- ZCCHC9 | c.*542_*548del | 3'UTR (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
